Somatic mutation profile of tumor specimen TCGA-A2-A0CV-01A (aliquot TCGA-A2-A0CV-01A-31D-A10Y-09) from TCGA case TCGA-A2-A0CV, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIB; Age at diagnosis: 41.9 years (15,289 days).
Specimen TCGA-A2-A0CV-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d15a2772-6752-414d-8d5a-89fc36cc21c1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A2-A0CV-10A (Blood Derived Normal), aliquot TCGA-A2-A0CV-10A-01D-A110-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2222cb0a-59a2-41ac-9ad2-eaa3bf03e7c3

The open-access MAF lists 22 somatic variants for this specimen: 19 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 16, Silent 3, Nonsense Mutation 2, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCB10 | c.766C>G p.L256V | Missense Mutation (SNP) | VAF 20/139 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.291); catalogued as COSV60619322; called by muse, mutect2, varscan2
- AGO2 | c.1378C>T p.R460C | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.674); catalogued as COSV55046684; called by muse, mutect2, varscan2
- AHNAK | c.6349A>G p.I2117V | Missense Mutation (SNP) | VAF 55/341 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0.156); catalogued as COSV57232503; called by muse, mutect2, varscan2
- ANPEP | c.1088G>A p.R363Q | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.844); catalogued as rs141631662; called by muse, mutect2, varscan2
- CARD9 | c.172A>G p.K58E | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.9); catalogued as COSV53738176; called by muse, mutect2
- CMYA5 | c.7807G>A p.A2603T | Missense Mutation (SNP) | VAF 13/95 reads (14%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); catalogued as rs770958823, COSV71409864; called by muse, mutect2, varscan2
- CPT1B | c.2122G>A p.A708T | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.164); catalogued as rs757184617, COSV56414818; called by muse, mutect2, varscan2
- GATA3 | c.922-3_922-2del p.X308_splice | Splice Site (DEL) | VAF 39/112 reads (35%) | catalogued as rs763236375, COSV60515023; called by mutect2, pindel, varscan2
- GNE | c.2144G>A p.R715H (on ENST00000396594 / NM_001128227.3; = p.R684H on NM_005476.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/132 reads (16%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as rs549097855, COSV64953254; called by muse, mutect2, varscan2
- GOLGB1 | c.4113G>T p.Q1371H | Missense Mutation (SNP) | VAF 33/182 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.179); catalogued as COSV61471719; called by muse, mutect2, varscan2
- HS2ST1 | c.384A>G p.I128M | Missense Mutation (SNP) | VAF 19/134 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.243); catalogued as COSV63353251; called by muse, mutect2, varscan2
- LRBA | c.8009A>G p.Y2670C | Missense Mutation (SNP) | VAF 18/109 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV63965922; called by muse, mutect2, varscan2
- ROBO1 | c.1409G>C p.G470A | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.703); catalogued as COSV71398880; called by muse, mutect2, varscan2
- SNTA1 | c.1513G>T p.A505S | Missense Mutation (SNP) | VAF 19/101 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV54130994; called by muse, mutect2, varscan2
- SYT16 | c.703G>A p.G235R | Missense Mutation (SNP) | VAF 19/132 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs1413075127, COSV70855944; called by muse, mutect2, varscan2
- SYT5 | c.70C>T p.H24Y | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as COSV54750568; called by muse, mutect2, varscan2
- TOGARAM1 | c.109C>T p.R37* | Nonsense Mutation (SNP) | VAF 9/42 reads (21%) | catalogued as rs1260189022, COSV61889463; called by muse, mutect2, varscan2
- TUBA1C | c.462G>T p.M154I | Missense Mutation (SNP) | VAF 32/172 reads (19%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.022); catalogued as COSV56511864; called by muse, mutect2, varscan2
- ZC3H4 | c.1003C>T p.R335* | Nonsense Mutation (SNP) | VAF 20/121 reads (17%) | catalogued as COSV53417141; called by muse, mutect2, varscan2
- PCDHA12 | c.1749G>A p.R583= | Silent (SNP) | VAF 28/142 reads (20%) | catalogued as COSV56550077; called by muse, mutect2, varscan2
- TMEM132D | c.1584C>T p.I528= | Silent (SNP) | VAF 16/89 reads (18%) | catalogued as rs565021234, COSV67158531; called by muse, mutect2, varscan2
- VWA3A | c.1827G>A p.S609= | Silent (SNP) | VAF 14/75 reads (19%) | catalogued as rs780664133, COSV55395409; called by muse, mutect2, varscan2
